Somatic mutation profile of tumor specimen TCGA-ZM-AA0H-01A (aliquot TCGA-ZM-AA0H-01A-11D-A435-10) from TCGA case TCGA-ZM-AA0H, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Seminoma, NOS; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage IS; Age at diagnosis: 50.4 years (18,419 days).
Specimen TCGA-ZM-AA0H-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4b82d026-f4bd-4622-bfe1-e6d61cb1875d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ZM-AA0H-10A (Blood Derived Normal), aliquot TCGA-ZM-AA0H-10A-01D-A438-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b8aa1a36-6bae-4f0d-98d3-b578a5eefe8d

The open-access MAF lists 40 somatic variants for this specimen: 22 protein-altering or splice-affecting, 14 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 20, Silent 14, Intron 3, Frame Shift Del 2, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KIT | c.2485G>C p.A829P | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs1057519713, COSV55414160; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AFDN | c.598G>A p.A200T | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.179); catalogued as COSV60052374; called by muse, mutect2, varscan2
- ATP2B2 | c.1262G>C p.C421S (on ENST00000352432; = p.C387S on NM_001683.5) | Missense Mutation (SNP) | VAF 14/114 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as COSV59505896; called by muse, mutect2, varscan2
- H3C3 | c.331_332del p.C111Rfs*5 | Frame Shift Del (DEL) | VAF 6/60 reads (10%) | catalogued as rs761955716; called by pindel, varscan2
- NAV3 | c.6376G>C p.D2126H (on ENST00000397909 / NM_001024383.2; = p.D2104H on NM_014903.6) | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99886905; called by muse, mutect2, varscan2
- SKAP1 | c.19C>T p.P7S | Missense Mutation (SNP) | VAF 6/65 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.444); catalogued as COSV61147455; called by muse, mutect2
- ATG2B | c.5326C>G p.Q1776E | Missense Mutation (SNP) | VAF 18/147 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CASKIN2 | c.41G>C p.G14A | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.526); called by muse, mutect2, varscan2
- CHD1 | c.1202A>T p.K401M | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.34); called by muse, mutect2, varscan2
- DARS2 | c.601C>A p.L201I | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.713); called by muse, mutect2, varscan2
- HOOK3 | c.302C>G p.P101R | Missense Mutation (SNP) | VAF 10/116 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- INO80 | c.3341A>C p.K1114T | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- LRP1B | c.11918A>G p.D3973G | Missense Mutation (SNP) | VAF 12/114 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MAB21L3 | c.597G>T p.K199N | Missense Mutation (SNP) | VAF 16/175 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- MTIF2 | c.811G>A p.E271K | Missense Mutation (SNP) | VAF 29/163 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PPM1H | c.331A>T p.T111S | Missense Mutation (SNP) | VAF 19/121 reads (16%) | SIFT tolerated (0.9); PolyPhen benign (0); called by muse, mutect2, varscan2
- PTGER3 | c.521C>T p.T174I | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- RNASEH2C | c.299G>T p.R100L | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- SPINT2 | c.366_370del p.H122Qfs*7 | Frame Shift Del (DEL) | VAF 6/56 reads (11%) | called by mutect2, pindel
- TENM3 | c.3589A>T p.I1197L | Missense Mutation (SNP) | VAF 28/133 reads (21%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.785); called by muse, mutect2, varscan2
- WASF2 | c.1135C>T p.P379S | Missense Mutation (SNP) | VAF 23/175 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.026); called by muse, varscan2
- ZNF184 | c.1697C>T p.T566I | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.159); called by muse, mutect2, varscan2
- BEND4 | c.939G>A p.E313= | Silent (SNP) | VAF 4/78 reads (5%) | called by muse, mutect2
- COL11A2 | c.3181C>A p.R1061= (on ENST00000341947 / NM_080680.3; = p.R954= on NM_080679.2) | Silent (SNP) | VAF 6/78 reads (8%) | catalogued as COSV100554440; called by muse, mutect2
- GART | c.1893G>A p.V631= | Silent (SNP) | VAF 5/64 reads (8%) | called by muse, mutect2
- HEATR5B | c.4431A>G p.L1477= | Silent (SNP) | VAF 8/78 reads (10%) | catalogued as rs762474415; called by muse, mutect2, varscan2
- KIF5A | c.1395G>A p.K465= | Silent (SNP) | VAF 5/61 reads (8%) | catalogued as rs1197765347, COSV54051359; called by muse, mutect2
- NTNG1 | c.273G>A p.E91= | Silent (SNP) | VAF 12/182 reads (7%) | catalogued as rs1030742360; called by muse, mutect2
- PCDH18 | c.630A>C p.S210= | Silent (SNP) | VAF 6/61 reads (10%) | called by muse, mutect2, varscan2
- POU2F2 | c.1035C>T p.F345= (on ENST00000526816 / NM_001207025.3; = p.F329= on NM_002698.5) | Silent (SNP) | VAF 6/41 reads (15%) | catalogued as rs369799078; called by muse, mutect2, varscan2
- RNPS1 | c.546C>A p.S182= | Silent (SNP) | VAF 14/57 reads (25%) | called by mutect2, varscan2
- SLC39A6 | c.1368G>A p.K456= | Silent (SNP) | VAF 11/67 reads (16%) | called by muse, mutect2, varscan2
- SLC9A3R2 | c.723C>G p.V241= | Silent (SNP) | VAF 7/97 reads (7%) | called by muse, mutect2
- TTC3 | c.795C>T p.Y265= | Silent (SNP) | VAF 16/159 reads (10%) | called by muse, mutect2, varscan2
- YWHAQ | c.597C>T p.A199= | Silent (SNP) | VAF 19/160 reads (12%) | catalogued as rs1170546582, COSV53004570; called by muse, mutect2, varscan2
- ZNF276 | c.732C>G p.T244= (on ENST00000443381 / NM_001113525.2; = p.T169= on NM_152287.4) | Silent (SNP) | VAF 11/131 reads (8%) | called by muse, mutect2
- ATAD3B | c.*723C>A | 3'UTR (SNP) | VAF 5/34 reads (15%) | called by muse, mutect2
- FAM204A | c.353+34G>A | Intron (SNP) | VAF 10/120 reads (8%) | called by muse, mutect2
- RPS7 | c.507+46_507+47del | Intron (DEL) | VAF 8/70 reads (11%) | catalogued as rs1264076103; called by pindel, varscan2
- UCKL1 | c.923+1010C>G | Intron (SNP) | VAF 7/56 reads (13%) | called by muse, mutect2, varscan2
